Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SL-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DIAGNOSIS:

A. Left kidney: Papillary renal cell carcinoma, grade 1/4, 4 cm, confined to the kidney.

Procedure/laterality: Left robotic nephrectomy.

Histologic type: Papillary renal cell carcinoma, type I.

Nuclear grade (Fuhrman, 1-4): Grade 1/4.

Tumor size: 4 x 3.7 x 3.7 cm.

Tumor site: Upper pole left kidney.

Tumor focality: A single circumscribed lesion in the cortex.

Sarcomatoid features: Absent.

Tumor necrosis: Absent.

Microscopic tumor extension: No extension into perinephric tissue, renal sinus, renal vein or collecting system.

Surgical margins: The external soft tissue and ureteral margins are negative for carcinoma.

Lymph-vascular invasion: Absent.

Lymph nodes: Absent.

Pathologic findings in nonneoplastic kidney: Adjacent to the carcinoma there is a 2 cm unilocular renal cyst.

Sections of cortex away from the carcinoma show less than 5% sclerotic glomeruli, minimal interstitial fibrosis, some dilated atrophic tubules, and severe renal artery and intra-renal artery atherosclerosis.

Pathologic staging: pT1a, pNX.

Biorepository sample (if applicable): Yes, non-malignant cortex and carcinoma.

Block(s) containing malignancy suitable for additional testing: A1, A3, A4, A5.

The frozen section diagnosis is confirmed by the permanent sections.

ICD-O-3

Carcinoma papillary renal cell
8260/3

Site ① Kidney C64.9

10/4/13

CLINICAL INFORMATION:

[page 2 of 2]
Left renal mass.

SPECIMEN(S):

A:Left kidney

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

A. Left kidney, frozen section diagnosis: Papillary renal cell carcinoma.

GROSS DESCRIPTION:

and "left kidney".

Procedure: Radical nephrectomy.

Specimen laterality: Left.

Tumor site: Upper pole.

Tumor size: 4.0 x 3.7 x 3.7 cm.

Tumor focality: Unifocal.

Gross extent of tumor:

Extension into perinephric tissue: Absent.

Extension beyond Gerota's fascia: Absent.

Extension into renal sinus: Absent.

Extension into renal vein: Absent.

Extension into collecting system: Absent.

Adrenal gland: Absent.

Gross notes:

Gross tumor characteristics: Well-demarcated, tan and a rubbery mass with somewhat lobulated-appearing cut surfaces with a couple foci of yellow-orange, moderately soft areas measuring up to 1.2 cm in greatest dimension.

Kidney weight: 564 g with fat; weight without fat 165 g.

Kidney dimensions: 11.5 x 6.0 x 4.7 cm.

Ureter dimensions: Length--8.5 cm and diameter--0.4 cm.

Lymph nodes: None identified.

Inking details: The outer-most surface of the fat adjacent to the mass is inked blue.

Biorepository sample submitted: Yes, see block key.

Other findings: Abutting the mass, there is a 2.0-cm in greatest dimension unilocular cyst compartment containing tan, clear fluid. The inner cyst lining is smooth.

Block key for specimen A:

A1) representative section of mass submitted for frozen section

A2) ureter margin and vascular margins at hilum, shave

A3-A4) mass in relation to inked outer surface of adjacent fat

A5) mass in relation to adjacent cystic structure

A6) mass in relation to adjacent parenchyma and superior calyx

A7) inferior pole, to include parenchyma and inferior calyx

A8) mirror image of tissue submitted for (grossly normal parenchyma and tumor)

Source: NCI Genomic Data Commons file 21cf4855-e90b-4bc9-b141-c89aa2ef1f5a (TCGA-SX-A7SL.C495D1B8-5AAE-425D-B11B-77C84F928280.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).